Gene-level copy-number profile of tumor specimen TCGA-AG-A01J-01A from TCGA case TCGA-AG-A01J, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 59.1 years (21,581 days).
Specimen TCGA-AG-A01J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.9a20747a-36fb-4e9f-85a9-a470f6db76c2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-A01J-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6d162ff3-b810-4170-bc16-b87cdc8d6cd1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 471; copy number 1: 6,050; copy number 2: 44,606; copy number 3: 6,125; copy number 4: 138; copy number 5: 234; copy number 6: 1,395; copy number 7: 793.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AG-A01J-01A-01D-A008-01): tumor purity 0.5, ploidy 2.16, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 461 genes in 77 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:171,670,517–171,824,959, 10 genes: PFN1P1, RPL4P3, VAMP4, Z98751.1, Z98751.3, Z98751.2, AL135931.1, EEF1AKNMT, AL031864.1, AL031864.2.
- chr2:64,450,096–64,616,556, 8 genes: AC008074.1, LGALSL, LINC01805, AC008074.2, AFTPH, MIR4434, RNU6-100P, LINC02579.
- chr2:130,836,914–131,521,573, 45 genes (within-gene range 0–2): ARHGEF4, AC112786.1, AC112786.2, SMIM39, FAM168B, PLEKHB2, NEK2P4, AC009477.1, NF1P8, AC131180.1, MED15P8, POTEE, RNU6-127P, FAR2P4, KLF2P4, AC073869.5, ARHGAP42P1, AC073869.7, SSBP3P2, RAB6D, AC073869.3, MTCYBP10, MTND6P10, MTND5P23, MTND4P21, AC073869.4, MTND3P18, MTCO3P18, MTATP6P4, MTCO2P18, MTCO1P18, MTND2P18, MTND1P26, MED15P3, AC073869.2, LINC01120, AC073869.6, GNAQP1, NOC2LP2, RHOQP2, AC073869.1, MZT2A, TUBA3D, MIR4784, SMPD4BP.
- chr3:71,675,414–71,786,425, 4 genes (within-gene range 0–2): EIF4E3, GPR27, PROK2, AC096970.1.
- chr3:142,960,650–143,131,893, 6 genes (within-gene range 0–1): PAQR9-AS1, U2SURP, AC026304.1, AC018450.2, CHST2, AC018450.1.
- chr3:177,294,442–177,349,166, 3 genes: LINC00501, ASS1P7, AC117465.1.
- chr5:55,160,167–55,233,608, 6 genes: GPX8, MIR449A, MIR449B, MIR449C, MCIDAS, CCNO.
- chr5:56,815,549–56,971,675, 7 genes: MAP3K1, AC008937.2, AC008937.1, SETD9, MIER3, AC008937.3, AC016644.1.
- chr5:157,731,420–157,760,709, 3 genes (within-gene range 0–2): THG1L, LSM11, AC026407.1.
- chr5:180,784,780–180,861,285, 6 genes (within-gene range 0–2): MGAT1, AC022413.1, HEIH, LINC00847, AC022413.2, ZFP62.
- chr6:2,948,159–3,303,373, 20 genes (within-gene range 0–2): SERPINB6, LINC01011, NQO2, NQO2-AS1, HTATSF1P2, AL133351.4, AL133351.3, FAM136BP, SERPINB8P1, AL031963.2, RIPK1, AL031963.3, RNA5SP201, BPHL, AL031963.1, TUBB2A, TUBB2BP1, LINC02525, TUBB2B, PSMG4.
- chr6:13,486,294–14,214,374, 17 genes: GFOD1-AS1, RPS4XP7, RN7SKP204, SIRT5, AL441883.1, NOL7, RANBP9, Z93020.1, MCUR1, AL023583.1, RNF182, MRPL35P1, AL022396.1, CD83, AL133259.1, RNU7-133P, AL353152.2.
- chr7:127,295,620–127,431,924, 5 genes (within-gene range 0–3): PRELID3BP10, ZNF800, AC000123.2, AC000123.1, AC000123.3.
- chr8:614,746–1,801,711, 17 genes (within-gene range 0–1): ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1.
- chr8:1,801,125–1,817,307, 3 genes: MIR3674, AC100810.7, MIR596.
- chr8:8,701,937–8,895,918, 5 genes: CLDN23, AC087269.2, AC087269.1, MFHAS1, RNU6-682P.
- chr9:95,494,924–95,514,520, 3 genes: AL161729.2, AL161729.1, AL161729.4.
- chr9:111,631,334–111,670,229, 3 genes: DNAJC25, DNAJC25-GNG10, GNG10.
- chr10:68,230,595–68,261,499, 3 genes: ATOH7, LINC02640, KRT19P4.
- chr10:114,764,788–114,811,170, 2 genes: AL137025.1, TAF9BP2.
- chr10:119,208,531–119,213,146, 2 genes: GRK5-IT1, RN7SL749P.
- chr12:42,081,845–42,590,355, 14 genes (within-gene range 0–2): GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3.
- chr12:67,648,338–67,670,919, 2 genes (within-gene range 0–2): DYRK2, AC078777.1.
- chr13:53,193,667–53,202,753, 2 genes: AL136359.1, PCDH8P1.
- chr14:95,516,136–95,534,889, 2 genes (within-gene range 0–2): AL133467.1, SNHG10.
- chr15:34,341,719–35,860,199, 43 genes (within-gene range 0–1): NOP10, NUTM1, LPCAT4, ACTG1P15, GOLGA8A, MIR1233-1, AC025678.1, AC025678.2, AC025678.3, HNRNPLP2, FSCN1P1, DNM1P5, GOLGA8B, MIR1233-2, AC027139.1, AC100834.1, LINC02252, AC100834.2, GJD2, AC087457.1, ACTC1, TUBAP11, AQR, AC018868.1, ZNF770, AC114546.3, AC114546.1, AC114546.4, AC114546.2, AC021231.3, NANOGP8, AC021231.2, AC021231.1, PRELID1P4, ANP32AP1, DPH6, NUTF2P6, RBM17P4, MIR3942, AC019288.1, HNRNPA1P45, DPH6-DT, AC068867.1.
- chr15:97,945,208–97,973,833, 2 genes (within-gene range 0–1): AC024651.3, ARRDC4.
- chr16:48,470,953–48,498,601, 2 genes: AC026470.1, MOCS1P1.
- chr16:58,157,907–58,217,805, 3 genes (within-gene range 0–2): CSNK2A2, AC009107.1, RN7SL645P.
- chr16:86,474,529–86,597,639, 10 genes (within-gene range 0–3): FENDRR, FOXF1, AC009108.3, AC009108.1, MTHFSD, FLJ30679, FOXC2-AS1, FOXC2, FOXL1, AC009108.4.
- chr18:47,390–927,993, 35 genes: TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904.
- chr18:26,542,971–26,575,626, 2 genes (within-gene range 0–1): AC007996.1, AC090206.1.
- chr18:32,470,288–33,751,195, 12 genes: AC025887.2, WBP11P1, AC009835.1, AC025887.1, KLHL14, AC012123.1, AC012123.2, AC090371.2, CCDC178, AC090371.1, AC091198.1, ASXL3.
- chr18:79,496,058–80,247,514, 26 genes: AC018445.4, AC018445.2, AC018445.6, AC068473.3, AC068473.4, AC068473.1, AC068473.5, CTDP1, AC068473.2, AC021594.1, AC021594.2, KCNG2, AC114341.1, SLC66A2, AC114341.2, HSBP1L1, TXNL4A, AC090360.1, RBFA, RBFADN, SLC25A6P4, ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.
- chr20:87,250–675,802, 22 genes: DEFB125, DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1, C20orf96, ZCCHC3, AL034548.2, NRSN2-AS1, SOX12, NRSN2, TRIB3, RBCK1, TBC1D20, Y_RNA, CSNK2A1, TCF15, SRXN1, AL121758.1, SCRT2.
- chr20:17,941,597–18,381,484, 20 genes (within-gene range 0–1): SNX5, OVOL2, SNORD17, MGME1, PTMAP3, AL160411.1, RPL15P1, RNU7-137P, Y_RNA, KAT14, PET117, GGCTP2, RN7SL14P, RNU2-56P, AL049646.2, ZNF133, AL049646.1, RN7SKP74, ZNF133-AS1, LINC00851.
- chr20:23,010,209–23,049,672, 4 genes (within-gene range 0–1): AL049651.1, AL049651.2, SSTR4, THBD.
- chr21:39,313,935–39,349,647, 4 genes: BRWD1-AS2, BRWD1-AS1, HMGN1, Y_RNA.
- chr21:41,798,225–42,010,387, 6 genes: PRDM15, AP001619.2, AP001619.1, AP001619.3, C2CD2, ZBTB21.
- chr22:50,541,108–50,801,309, 21 genes: U62317.3, KLHDC7B-DT, KLHDC7B, SYCE3, CPT1B, CHKB-CPT1B, CHKB, CHKB-DT, U62317.2, MAPK8IP2, ARSA, Y_RNA, AC000050.2, SHANK3, RNU6-409P, AC000036.1, ACR, AC002056.2, AC002056.1, RPL23AP82, RABL2B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,422 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:41,261,962–60,623,644, 298 genes, copy number 6 (broad region; genes not listed).
- chr8:60,678,740–73,063,061, 183 genes, copy number 7 (within-gene range 0–7) (broad region; genes not listed).
- chr8:73,215,929–96,127,801, 352 genes, copy number 6 (broad region; genes not listed).
- chr8:96,222,947–145,066,685, 775 genes, copy number 5–7 (broad region; genes not listed).
- chr14:22,011,910–22,507,723, 69 genes, copy number 5 (broad region; genes not listed).
- chr20:28,563,850–58,161,150, 714 genes, copy number 6 (broad region; genes not listed).
- chr20:59,300,443–61,940,617, 31 genes, copy number 6: EDN3, AL035250.1, AL035250.2, AL160410.1, PIEZO1P1, AL389889.2, AL389889.1, PHACTR3, PHACTR3-AS1, RNU7-141P, SYCP2, FAM217B, PPP1R3D, CDH26, C20orf197, AL132822.1, MIR646HG, MIR646, MTCO2P1, MIR4533, MIR548AG2, AL117372.1, AL139348.1, AL121910.1, LINC01718, CDH4, AL365229.1, BX640515.1, AL160412.1, AL162457.1, AL162457.2.

Autosomal genes at a single copy (total copy number 1): 6,050. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
